Somatic mutation profile of tumor specimen 0DON57 from CCDI case PBCCVU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: External ear; Age at diagnosis: 0.9 years (341 days).
Specimen 0DON57: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ca14be6-f940-4a8e-a3e8-8a1151b4f643.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DON4V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a74db65-e344-4fcd-a2eb-f79ccf617d5b

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 395/548 reads (72%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.385); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.448+1G>A p.X150_splice | Splice Site (SNP) | VAF 106/583 reads (18%) | catalogued as rs772137973; called by muse, mutect2, varscan2
- ESF1 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 102/1274 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.017); catalogued as rs137873021; called by muse, mutect2
- MLLT1 | c.142G>C p.V48L | Missense Mutation (SNP) | VAF 26/874 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV53132471; called by muse, mutect2
- TENT5A | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 124/783 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV60789822; called by muse, mutect2, varscan2
- ARNTL | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 64/307 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GOLT1B | c.240T>G p.I80M | Missense Mutation (SNP) | VAF 33/1142 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2
- MEIOB | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 113/422 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC19 | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 73/370 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SAMD10 | c.187C>A p.L63I | Missense Mutation (SNP) | VAF 29/490 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2
- SLC45A2 | c.680C>A p.T227N | Missense Mutation (SNP) | VAF 152/644 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- SSTR3 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 54/445 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- SYNE2 | c.20252A>T p.K6751M | Missense Mutation (SNP) | VAF 218/752 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- CD163L1 | c.1245C>T p.S415= | Silent (SNP) | VAF 90/387 reads (23%) | catalogued as COSV100549714; called by muse, mutect2, varscan2
- HSPA6 | c.1539C>T p.S513= | Silent (SNP) | VAF 66/934 reads (7%) | called by muse, mutect2
- ROBO1 | c.3318A>G p.K1106= | Silent (SNP) | VAF 130/1644 reads (8%) | called by muse, mutect2
- RYR2 | c.12177G>A p.T4059= | Silent (SNP) | VAF 36/696 reads (5%) | catalogued as rs1311120147, COSV63710124; ClinVar: likely benign; called by muse, mutect2
- TRIML1 | c.1149C>T p.I383= | Silent (SNP) | VAF 123/413 reads (30%) | catalogued as rs758081985, COSV60193621; called by muse, mutect2, varscan2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 6/74 reads (8%) | catalogued as COSV55814242; called by muse, mutect2
